Gene-level copy-number profile of tumor specimen HCM-CSHL-0092-C25-01A from HCMI case HCM-CSHL-0092-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 69.3 years (25,328 days).
Specimen HCM-CSHL-0092-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b32cddfa-7bd1-46c7-910f-f4f9b81635c4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0092-C25-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/d876e147-395f-44f3-b133-4ca2acbe0db4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 515; copy number 1: 8,980; copy number 2: 44,907; copy number 3: 3,476; copy number 4: 823; copy number 5: 208.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,486,926–49,508,806, 3 genes: AC119751.3, ANKRD20A17P, AC119751.5.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 208 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:737,628–1,708,476, 1 gene, copy number 5 (within-gene range 4–5): DLGAP2.
- chr8:1,246,789–8,244,865, 158 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:11,202,965–11,999,468, 31 genes, copy number 5: AF131215.7, LINC00529, RPL19P13, AF131216.2, AF131216.4, MTMR9, AF131216.1, SLC35G5, TDH, AF131216.3, FAM167A-AS1, RN7SL293P, RNU6-1084P, FAM167A, BLK, AC022239.1, LINC00208, GATA4, C8orf49, NEIL2, SUB1P1, FDFT1, AC069185.1, CTSB, AC025857.1, OR7E158P, OR7E161P, DEFB136, DEFB135, DEFB134, AC107918.3.
- chr8:97,624,203–98,294,393, 18 genes, copy number 5: AP002982.1, MTDH, Y_RNA, LAPTM4B, AP003357.1, AP002906.1, SUMO2P18, RPS23P1, MATN2, RPL30, AP003352.1, SNORA72, RNU6-703P, ERICH5, RIDA, POP1, NIPAL2, RNU6-914P.

Autosomal genes at a single copy (total copy number 1): 6,636. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
